Somatic mutation profile of tumor specimen TCGA-24-1426-01A (aliquot TCGA-24-1426-01A-01W-0549-09) from TCGA case TCGA-24-1426, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 43.7 years (15,949 days).
Specimen TCGA-24-1426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 423ea413-9c5b-451b-96df-7a94a16410ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1426-10A (Blood Derived Normal), aliquot TCGA-24-1426-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c28b1b6-7dd1-486a-8892-f90c2fc72e14

The open-access MAF lists 107 somatic variants for this specimen: 77 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 25, Nonsense Mutation 6, RNA 3, Frame Shift Del 3, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 83/89 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABTB1 | c.474C>A p.H158Q (on ENST00000232744 / NM_172027.3; = p.H16Q on NM_032548.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99229779; called by muse, mutect2
- AC100868.1 | c.1836C>A p.C612* | Nonsense Mutation (SNP) | VAF 47/61 reads (77%) | catalogued as COSV51846588; called by muse, mutect2, varscan2
- ADAMTS5 | c.2035G>T p.V679L | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99537550; called by muse, mutect2, varscan2
- ADGRG7 | c.2323C>G p.L775V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV99840986; called by muse, mutect2
- ANK1 | c.4393G>T p.E1465* | Nonsense Mutation (SNP) | VAF 10/192 reads (5%) | catalogued as COSV99225115; called by muse, mutect2
- ANKAR | c.3772C>A p.Q1258K | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55612662, COSV99854199; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs770581341, COSV51853165; called by muse, mutect2, varscan2
- ANKRD42 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 52/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99473781; called by muse, mutect2, varscan2
- AP002512.3 | c.23C>A p.T8K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.02); catalogued as COSV100392494; called by muse, mutect2
- BBS2 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV99802389; called by muse, mutect2
- C2CD2L | c.2096C>A p.A699D | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV100371193; called by muse, mutect2
- CDH9 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50263340, COSV50342466; called by muse, mutect2, varscan2
- CNTRL | c.6825C>A p.H2275Q | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV99442221; called by muse, mutect2
- COL2A1 | c.1025G>C p.G342A | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV61531084; called by muse, mutect2
- COL4A3 | c.3754G>T p.A1252S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100516729, COSV100516814; called by muse, mutect2
- COMP | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV55875651; called by muse, mutect2, varscan2
- DCAF13 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52570416, COSV99885274; called by muse, mutect2
- DNAJB13 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); catalogued as COSV60104339; called by muse, mutect2
- EDRF1 | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 394/550 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV61765174, COSV61766687; called by muse, mutect2, varscan2
- EXOC2 | c.2644G>C p.E882Q | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100033539; called by muse, mutect2
- FAM98C | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 70/1072 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.136); catalogued as COSV99384973; called by muse, mutect2
- FERMT2 | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100448876; called by muse, mutect2
- FGR | c.1301G>T p.R434I | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV100925823; called by muse, mutect2, varscan2
- FXYD2 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 296/672 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139816783; called by muse, varscan2
- GPATCH1 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs762164746, COSV99403997; called by muse, mutect2
- GPR17 | c.87G>T p.M29I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.914); catalogued as COSV99760558; called by muse, mutect2
- GRHL2 | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52551532; called by muse, mutect2, varscan2
- HAUS7 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 64/480 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100444104; called by muse, mutect2, varscan2
- HTR4 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 13/412 reads (3%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.56); catalogued as rs1477356393, COSV104405660, COSV58799617; called by muse, mutect2
- ITIH5 | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99904569; called by muse, mutect2, varscan2
- KALRN | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53753850; called by muse, mutect2, varscan2
- KANSL2 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100770935; called by muse, varscan2
- KIAA2026 | c.1601C>A p.S534Y | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV101199020; called by muse, mutect2
- KLHDC9 | c.119T>A p.F40Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100919676; called by muse, mutect2, varscan2
- MYO1F | c.3158T>C p.V1053A | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.04); catalogued as COSV57797704; called by muse, mutect2, varscan2
- NCOA3 | c.3667G>T p.A1223S (on ENST00000371998 / NM_181659.3; = p.A1219S on NM_006534.4) | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.309); catalogued as COSV100507519; called by muse, mutect2
- NFE2L3 | c.2002C>A p.H668N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV99283677; called by muse, mutect2
- NMRAL1 | c.851C>G p.T284R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99361766; called by muse, mutect2, varscan2
- NUB1 | c.419T>C p.I140T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV100879268; called by muse, mutect2
- NUP107 | c.2122G>T p.A708S | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV99971731; called by muse, mutect2
- OR4C3 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100167802, COSV60584123; called by muse, mutect2, varscan2
- PACS2 | c.252dup p.S85Qfs*57 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs782816086; called by pindel, varscan2
- PANX1 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV57133505; called by muse, mutect2
- PCDHA2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.286); catalogued as COSV100973822; called by muse, mutect2, varscan2
- PCLO | c.12128C>T p.P4043L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100432075; called by muse, mutect2
- PITPNC1 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 22/813 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100083383; called by muse, mutect2
- POGLUT2 | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101050786; called by muse, mutect2
- PPFIA4 | c.911G>C p.R304P | Missense Mutation (SNP) | VAF 507/568 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55316369, COSV55318548; called by muse, mutect2, varscan2
- PPP1R13B | c.238del p.L80Ffs*27 | Frame Shift Del (DEL) | VAF 63/177 reads (36%) | catalogued as COSV52457203; called by mutect2, pindel, varscan2
- PSMD4 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100924664; called by muse, mutect2
- PTCHD1 | c.2098C>A p.L700M | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV101037625; called by muse, mutect2
- RABGEF1 | c.644A>G p.E215G (on ENST00000439720 / NM_001287061.2; = p.E202G on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV99534790; called by muse, mutect2
- RBM15B | c.2301G>T p.Q767H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100082112; called by muse, mutect2, varscan2
- RET | c.615G>T p.R205S | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV100393537; called by muse, mutect2
- ROBO1 | c.3202G>C p.G1068R | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV101458391, COSV101458683; called by muse, mutect2, varscan2
- RPA4 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61281545; called by muse, mutect2, varscan2
- SATB1 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100113156; called by muse, mutect2
- SDHAF2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV100073965; called by muse, mutect2, varscan2
- SEL1L2 | c.957C>A p.Y319* | Nonsense Mutation (SNP) | VAF 43/932 reads (5%) | catalogued as COSV53152177, COSV53159901; called by muse, mutect2
- SFN | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV100212809; called by muse, mutect2, varscan2
- SGCZ | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 292/630 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs761534961, COSV66019533, COSV66027498; called by muse, mutect2, varscan2
- SLC35B1 | c.1001G>A p.W334* (on ENST00000649906; = p.W297* on NM_005827.4) | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as COSV53603590; called by muse, mutect2, varscan2
- SLC66A3 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV99706210; called by muse, mutect2, varscan2
- SNAP47 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 71/98 reads (72%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs943855487, COSV100248122; called by muse, mutect2, varscan2
- SRP68 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57163721; called by muse, mutect2
- STK3 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101372518; called by muse, mutect2
- TBKBP1 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as rs760641888, COSV100659113; called by mutect2, varscan2
- TSHR | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV53326054, COSV53332226; called by muse, mutect2, varscan2
- UGT2B11 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV101485239, COSV101485246; called by muse, mutect2, varscan2
- USP51 | c.855C>A p.C285* | Nonsense Mutation (SNP) | VAF 28/252 reads (11%) | catalogued as COSV101540662; called by muse, mutect2, varscan2
- ZFHX4 | c.3784C>A p.Q1262K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV99262382; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1570A>G p.K524E | Missense Mutation (SNP) | VAF 80/806 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1313880727, COSV56273400; called by muse, varscan2
- AHNAK | c.5979_5998del p.D1993Efs*18 | Frame Shift Del (DEL) | VAF 66/255 reads (26%) | called by mutect2, pindel
- ATP2B1 | c.2138del p.N713Ifs*22 | Frame Shift Del (DEL) | VAF 120/318 reads (38%) | called by mutect2, pindel, varscan2
- CCL4L2 | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEC31B | c.646T>C p.C216R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- ACOX1 | c.849C>A p.S283= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as COSV99503352; called by muse, mutect2, varscan2
- AMIGO1 | c.1455C>A p.V485= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as COSV100881050, COSV100881115; called by muse, mutect2, varscan2
- ARID4A | c.2622A>T p.G874= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV62165191; called by muse, mutect2, varscan2
- ARSJ | c.1152C>T p.L384= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV59538855; called by muse, mutect2, varscan2
- ATG4D | c.867C>A p.A289= | Silent (SNP) | VAF 29/380 reads (8%) | catalogued as COSV100470072; called by muse, mutect2
- CAPN13 | c.1761C>A p.L587= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV99700200, COSV99700436; called by muse, mutect2, varscan2
- CCDC180 | c.3402T>A p.T1134= | Silent (SNP) | VAF 10/186 reads (5%) | catalogued as COSV100826673; called by muse, mutect2
- CRIM1 | c.2103C>T p.C701= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV54868646; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.435C>T p.T145= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as rs372175263; called by muse, mutect2, varscan2
- EPG5 | c.5124C>A p.G1708= | Silent (SNP) | VAF 6/149 reads (4%) | catalogued as COSV99957174; called by muse, mutect2
- FHOD1 | c.858G>T p.A286= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs752207424, COSV50764120; called by muse, mutect2, varscan2
- HNRNPM | c.444T>C p.P148= | Silent (SNP) | VAF 172/403 reads (43%) | catalogued as COSV100335128; called by muse, mutect2, varscan2
- KCNK10 | c.219T>G p.V73= | Silent (SNP) | VAF 89/172 reads (52%) | catalogued as COSV56648648; called by muse, mutect2, varscan2
- LGR5 | c.1200C>A p.L400= | Silent (SNP) | VAF 29/250 reads (12%) | catalogued as COSV57010438, COSV99877882; called by muse, mutect2, varscan2
- OTUB2 | c.396G>T p.V132= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV52574067; called by muse, mutect2, varscan2
- PLOD1 | c.1251C>T p.N417= | Silent (SNP) | VAF 117/158 reads (74%) | catalogued as COSV52147706; called by mutect2, varscan2
- POLR3C | c.492T>C p.P164= | Silent (SNP) | VAF 98/176 reads (56%) | catalogued as rs781790679, COSV61937009; called by muse, varscan2
- PROK1 | c.63G>A p.V21= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as COSV99602558; called by muse, mutect2, varscan2
- SEPTIN8 | c.684C>T p.N228= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs376667090; called by muse, mutect2, varscan2
- STX3 | c.51T>C p.D17= | Silent (SNP) | VAF 36/715 reads (5%) | catalogued as rs771168925, COSV100275841; called by muse, mutect2
- TMEM87B | c.249G>T p.G83= | Silent (SNP) | VAF 19/329 reads (6%) | catalogued as COSV99314271; called by muse, mutect2
- TMX3 | c.54A>T p.V18= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV55186422; called by muse, mutect2, varscan2
- TRIM51 | c.501C>T p.C167= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as COSV55268105, COSV99792562; called by muse, varscan2
- TSPAN1 | c.564C>T p.T188= | Silent (SNP) | VAF 132/439 reads (30%) | catalogued as COSV64340393; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1569C>T p.Y523= | Silent (SNP) | VAF 80/806 reads (10%) | catalogued as rs1319600347; called by muse, varscan2
- C7orf66 | n.87T>A | RNA (SNP) | VAF 80/99 reads (81%) | called by muse, mutect2, varscan2
- DCHS2 | n.3136A>T | RNA (SNP) | VAF 121/163 reads (74%) | catalogued as COSV59732909; called by muse, mutect2, varscan2
- PTBP1 | c.892+344C>T | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as COSV62461036; called by muse, mutect2, varscan2
- RMDN2 | c.452+21616C>A | Intron (SNP) | VAF 18/239 reads (8%) | catalogued as rs767191002, COSV99307668; called by muse, mutect2
- SERPINA13P | n.779G>T | RNA (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
